Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4798, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4798-01A (Primary Tumor).

[page 1 of 4]
TCGA-BP-4798

Accession #:

Date of Procedure:

Date of Receipt:

Date of Original Rep

Date of Amendment

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

with left renal mass.

Specimens Submitted:

1: Left renal vein margin; excision

2: Kidney, adrenal gland and lymph nodes; radical nephrectomy

AMENDED DIAGNOSIS:

1. Left renal vein margin; excision:

Benign vascular structure, no tumor seen.

2. Kidney, adrenal gland and lymph nodes; radical nephrectomy:

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type
with focal spindle cell/sarcomatoid features

Fuhrman Nuclear Grade:

Nuclear grade IV/IV

Tumor Size:

Greatest diameter is 9.5 cm.

Local Invasion (for renal cortical types):

Involves renal sinus fat

Renal Vein Invasion:

Identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Shows arteriosclerosis

Adrenal Gland:

Not involved

Lymph Nodes:

Number of nodes examined:30

Not involved

Staging for renal cell carcinoma/oncocytoma:

pT3b Tumor grossly extends into the renal vein(s) or vena cava below the diaphragm

[page 2 of 4]
Note:

This document represents an amended version of the surgical pathology report originally issued on [REDACTED]. That report is superseded by the present document. The amendment consists of the following change:

ORIGINAL REPORT:Diagnosis:

2. Lymph Nodes:
Number of nodes examined:30

Gross Description:AMENDED REPORT:Diagnosis:

2. Lymph Nodes:
Number of nodes examined:30
Not involved

Gross Description:

[REDACTED] responsible clinician has been notified.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

- 1). The specimen is received fresh for frozen section consultation, labeled "left renal vein margin" and consists of a 0.4 cm yellow-tan soft tissue. Entirely submitted for frozen section.

Summary of sections:
FSC -- frozen section control

- 2).The specimen is received fresh, labeled "left kidney, adrenal gland and lymph nodes" and consists of a kidney with attached ureter, renal vessels and perinephric fat weighing 753 g in total. The kidney measures 15.0 x 7.1 x 6.0 cm. The attached ureter measures 10.1 cm in length and 0.5 cm in diameter. The attached renal vein measures 1.5 cm in length and .0.9 cm in diameter. The renal vessels and ureter margins are grossly unremarkable. An adrenal gland is identified, measuring 5.9 x 2.0 x 0.9 cm. The kidney is inked black and bivalved to reveal a poorly delineated tumor 9.5 x 6.2 x 5.0 cm which is involving almost all of the upper pole of the kidney as well the lower pole. The tumor is impinging upon the renal pelvis but grossly does not appear to be involving the renal pelvis. Polypoid protrusion of the tumor is present in the renal vein but the margin of the vein is grossly negative of tumor. The tumor appears to be pushing the renal capsule but does not appear to be grossly invading the perirenal fat. Sections through the remainder of the kidney reveal a pink-brown parenchyma, with a well-defined cortico-medullary junction. The cortex measures 0.7 cm and the calyces appear normal. Multiple lymph nodes are identified in the perinephric fat. The specimen is photographed. Representative sections are submitted for TPS and for permanent sections.

Summary of sections:

[page 3 of 4]
UVM -- ureteral and vessel margins
T-- tumor
THF-- tumor with hilar fat
TSF -- tumor with sinus fat
TK -- tumor with adjacent kidney
RP -- renal pelvis representative sections
K -- representative sections kidney
AD -- adrenal gland
LNI-- Lymph nodes inferior
LNS -- Lymph nodes superior
At -- Additional section of the tumor

Summary of Sections:

Part 1: Left renal vein margin; excision

Block	Sect. Site	PCs
1	fsc	1

Part 2: Kidney, adrenal gland and lymph nodes; radical nephrectomy

Block	Sect. Site	PCs
1	AD	0
4	AT	4
1	K	0
4	LNI	0
3	LNS	0
1	RP	0
7	T	0
1	THF	0
1	TK	0
1	TSF	0
1	UVM	0

Amendments

Original Diagnosis:

1. Left renal vein margin; excision:
Benign vascular structure, no tumor seen.
2. Kidney, adrenal gland and lymph nodes; radical nephrectomy:
Tumor Type:
Renal cell carcinoma - Conventional (clear cell) type
with focal spindle cell/sarcomatoid features

Fuhrman Nuclear Grade:
Nuclear grade IV/IV

Tumor Size:
Greatest diameter is 9.5 cm.

Local Invasion (for renal cortical types):
Involves renal sinus fat

Renal Vein Invasion:
Identified

[page 4 of 4]
SURGICAL PATHOLOGIST REPORT

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Shows arteriosclerosis

Adrenal Gland:

Not Involved

Lymph Nodes:

Number of nodes examined:30

Staging for renal cell carcinoma/oncocytoma:

pT3b Tumor grossly extends into the renal vein(s) or vena cava below the diaphragm

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: BENIGN. [REDACTED]
[REDACTED] SAME.

Referring Physician Contacted

Source: NCI Genomic Data Commons file a82dd159-17db-4053-99c1-d7a2c69b17c5 (TCGA-BP-4798.033C89DE-CF03-4E4F-ACD1-7792BEA14524.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).